FM case AD3025 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/13bd76a1-bb01-46db-861c-ced6a0ffb567

Male, 46.1 years: Acinar adenocarcinoma (ICD-O-3 8550/3) of the prostate gland; primary biopsied or resected from the prostate gland. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
